Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6534, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6534-01A (Primary Tumor).

Examination: Histopathological examination

Examination No.: [REDACTED]

Patient: XXX

PESEL: XXX

Age [REDACTED] Gender: F

Material: Multiple organ resection – colon

Unit in charge: [REDACTED]

Physician in charge: [REDACTED]

Material collected on: [REDACTED]

Material received on: [REDACTED]

Expected time of examination: [REDACTED]

Clinical diagnosis: [REDACTED]

Examination performed on: [REDACTED]

Macroscopic description:

A 27 cm length of large intestine with periintestinal fat tissue sized 24 x 5 x 4 cm. Ulcerous tumour sized 1.8 x 1.5 x 0.7 cm in the mucosa.

Microscopic description:

Adenocarcinoma mucinosum [REDACTED]

Infiltratio carcinomatosa tunicae muscularis propriae telae adiposae pericolicae.

Incision lines free of neoplastic lesions. Lymphonodulitis reactiva NO XXII.

Histopathological diagnosis

Adenocarcinoma mucinosum coli. Mucinous adenocarcinoma of the colon.

[REDACTED], pT3, pNO) [REDACTED]

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file b872ecdb-047a-4cb4-ae2b-07469c0b543e (TCGA-D5-6534.637C02FE-9238-4474-BA5B-15719353895B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).